Surgical pathology report (de-identified scan), TCGA case TCGA-06-0747, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0747-01A (Primary Tumor).

[page 1 of 3]
TCGA-06-0747

Surgical Pathology Report

CLINICAL HISTORY

[REDACTED] with chronic hepatitis, cardiomyopathy and S/P renal transplantation complains of weakness and falling, x 3. On imaging patient has a 5.5-cm. intra axial, enhancing, necrotic mass in right frontal temporal lobe.

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, Right parietal, biopsy
B: Brain, right parietal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right parietal, excision: Glioblastoma. MIB-1 proliferation index: 12%.
See Microscopy Description and Comment.

COMMENT

The sections contain portions of an astrocytic neoplastic proliferation that infiltrates and extensively effaces the cerebrum. The neoplasm is small-celled, and has nuclear anaplastic features, mitotic figures, microvascular proliferation with vascular necrosis and thrombosis, and small zones of tumor necrosis. The neurons contained within the neoplasm are interpreted as non-neoplastic native neurons, and a neuronal component is considered unlikely.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products

[page 2 of 3]
[REDACTED]

detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right parietal, biopsy, smear and touch preps: Glioma, high histological grade. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, three fragments, 1.4-cm. in aggregate. Firm, glistening, grayish-blue, fish-fleshy. In total, A1 and A2.

B.

SPECIMEN: Right parietal brain tumor.

FIXATIVE: None.

GENERAL: Received are multiple pink-gray soft tissue fragments with scant amount of attached dark red clotted blood aggregating to 4 x 2 x 1 cm.

SECTIONS: B1-B3 entirely submitted.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates glial fibrillogenesis by the neoplastic cells. There are non-atypical neuronal elements (positive with synaptophysin, chromogranin, and NeuN) focally, in what appears to be cerebral cortex. With the MIB-1 there is a proliferation index of about 12% throughout the tumor.

SPECIAL STAIN: There is no reticulin deposition within the neoplasm.

The findings are consistent with a high histological grade astrocytic neoplasm. The neuronal cells do not appear neoplastic, and are interpreted as trapped native neurons.

ICD-9(s):

191.3 191.3

[REDACTED]

Histo Data

Part A: Brain, Right parietal, biopsy

[page 3 of 3]
Taken: [REDACTED] Received: [REDACTED]
Stain/cnt Block Ordered Comment
H/E x 1 1 [REDACTED]

Part B: Brain, right parietal tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	
ChromA-DA x 1	3	[REDACTED]	[REDACTED] also. Thank you.
mGFAP-DA x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
NF2F11 x 1	3	[REDACTED]	
Retic x 1	3	[REDACTED]	
Synap-DA x 1	3	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 037caf46-bf60-4de6-9127-9f27b0b2c6b2 (TCGA-06-0747.41920FBE-BE2C-4F3B-B8EE-6F2915A2AE3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).